Gene-level copy-number profile of tumor specimen TCGA-EJ-8472-01A from TCGA case TCGA-EJ-8472, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 63.3 years (23,104 days).
Specimen TCGA-EJ-8472-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.0085255e-1e3c-48b2-9e53-bfc5aa5bf7c6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EJ-8472-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f5a9e8ae-175c-433f-b582-0e49bda0b2c8

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 112; copy number 2: 7,938; copy number 3: 10,077; copy number 4: 35,715; copy number 5: 3,295; copy number 6: 1,994; copy number 7: 484; copy number 8: 167; copy number 9: 28; copy number 14: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EJ-8472-01A-11D-2391-01): tumor purity 0.62, ploidy 3.81, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 28 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:109,400,696–109,808,252, 6 genes, copy number 9: LINC00399, AL163541.1, LINC00676, IRS2, AL162497.1, AL355810.1.
- chr20:57,161,822–57,895,444, 22 genes, copy number 9: AL157414.3, BMP7, BMP7-AS1, AL122058.1, Y_RNA, MIR4325, RPL39P39, SPO11, RAE1, MTND1P9, MTRNR2L3, RBM38-AS1, RBM38, AL109955.1, HMGB1P1, CTCFL, PCK1, AL035541.1, ZBP1, PMEPA1, NKILA, AL162291.1.

Autosomal genes at a single copy (total copy number 1): 112. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
